Surgical pathology report (de-identified scan), TCGA case TCGA-19-2620, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Case Western, specimen TCGA-19-2620-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT**FINAL DIAGNOSIS**

A. LEFT FRONTAL MASS, B. LEFT FRONTAL TUMOR, C. LEFT SIDE FRONTAL TUMOR, E. RIGHT FRONTAL TUMOR LATERAL MARGIN, D. INFILTRATED WHITE MATTER, LEFT AND F. RIGHT FRONTAL TUMOR, BIOPSY AND EXCISION:
--GLIOBLASTOMA MULTIFORME (WHO GRADE IV).

Electronically Signed Out By

By the signature on this report, the individual or group listed as making the Final Interpretation/Diagnosis certifies that they have reviewed this case.

Intraoperative Consult Diagnosis

A: Touch Imprint: Glioblastoma.

Clinical History:

bifrontal brain lesions

Specimens Submitted As:

A:LEFT FRONTAL MASS
B:LEFT FRONTAL TUMOR
C:LEFT SIDE FRONTAL TUMOR
D:INFILTRATED WHITE MATTER LEFT
E:RIGHT FRONTAL TUMOR LATERAL MARGIN
F:RIGHT FRONTAL TUMOR

Gross Description:

A: Received fresh for intraoperative evaluation labeled with the patient's name, hospital number and "left frontal mass" are multiple irregularly shaped tan-pink soft tissue fragments, 1.4 x 1.2 x 0.5 cm in aggregate. A smear preparation is made for intraoperative diagnosis. The remainder of the specimen is entirely submitted in two cassettes.

B: Received fresh, post fixed in formalin, labeled with the patient's name and number, and "F L tumor", are multiple irregular, opaque white to tan brown, soft, cerebriform tissue fragments measuring in aggregate 7.0 x 5.5 x 1.6 cm. Representative sections are submitted in three cassettes.

C: Received fresh, post fixed in formalin, labeled with the patient's name and number, and "#1 LT side", are multiple irregular, opaque white to tan brown, soft, cerebriform tissue fragments measuring in aggregate 4.2 x 2.7 x 0.7 cm. Representative sections are submitted in three cassettes.

D: Received fresh, post fixed in formalin, labeled with the patient's name and number, and "LT infiltrated white matter", are multiple irregular, tan to brown, soft, cerebriform tissue fragments measuring in aggregate 2.0 x 1.4 x 0.5 cm. Submitted in toto in two cassettes.

[page 2 of 2]
[REDACTED]

E: Received fresh, post fixed in formalin, labeled with the patient's name and number, and "R frontal tumor, #2, lateral margin", are two irregular, opaque white to pale tan, soft, cerebriform tissue fragments measuring in aggregate 1.3 x 0.6 x 0.5 cm. Submitted in toto in one cassette.

F: Received fresh, post fixed in formalin, labeled with the patient's name and number, and "R frontal tumor 1", are multiple irregular, opaque white to tan-brown, soft, cerebriform tissue fragments measuring in aggregate 11.0 x 4.4 x 3.1 cm. A 2 x 2 x 2 cm piece of tumor and a small fragment of normal were given to [REDACTED]. Representative sections of the remaining tissue are submitted in three cassettes.

Source: NCI Genomic Data Commons file dc7379d8-5e8a-491f-b8e5-74f1af43c505 (TCGA-19-2620.DEDD3BD8-B885-498E-A305-50B727240D09.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).